CCDI case PBCDJM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/bf932690-5db1-49b2-b432-6ae56f2018cf

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 7.8 years (2,864 days).

Biospecimens (3 samples)
- Sample 0DPAOC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPAOG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DPAOY: Tissue type: Tumor; Specimen type: Solid Tissue.
